Somatic mutation profile of tumor specimen TCGA-S9-A6WP-01A (aliquot TCGA-S9-A6WP-01A-12D-A34A-08) from TCGA case TCGA-S9-A6WP, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 42.9 years (15,658 days).
Specimen TCGA-S9-A6WP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca08aec1-e3d7-43aa-b397-f390aa54fed7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WP-10A (Blood Derived Normal), aliquot TCGA-S9-A6WP-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49f9310f-1c47-405b-a993-ccbca8edfb39

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Frame Shift Del 8, Silent 5, In Frame Del 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 47/127 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NF1 | c.3739_3742del p.F1247Ifs*18 | Frame Shift Del (DEL) | VAF 53/288 reads (18%) | catalogued as rs1064794276; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTN1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as rs761658735, COSV99517185; called by muse, mutect2, varscan2
- CDC6 | c.1084-1G>A p.X362_splice | Splice Site (SNP) | VAF 46/125 reads (37%) | catalogued as COSV52931488, COSV99266484; called by muse, mutect2, varscan2
- CFAP47 | c.1605A>G p.I535M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.266); catalogued as COSV99934271; called by muse, mutect2, varscan2
- ENTPD7 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.067); catalogued as COSV100978337; called by muse, mutect2
- GOSR2 | c.359G>A p.R120Q (on ENST00000393456 / NM_001321134.1; = p.R185Q on NM_004287.5) | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1418311186, COSV99845919; called by muse, mutect2, varscan2
- HYDIN | c.6740C>T p.A2247V | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV59273873; called by muse, mutect2, varscan2
- ITGAX | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 62/166 reads (37%) | catalogued as rs1288044879, COSV99191415; called by muse, mutect2, varscan2
- KCTD16 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV72580172; called by muse, mutect2, varscan2
- LARGE2 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV99138030; called by muse, mutect2, varscan2
- MED16 | c.1_2del p.M1? | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | catalogued as rs776675168; called by mutect2, pindel, varscan2
- NF1 | c.2589T>A p.Y863* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100645961; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV59014807; called by muse, mutect2
- RNF220 | c.554_556del p.K185del | In Frame Del (DEL) | VAF 6/51 reads (12%) | catalogued as rs772081427; called by pindel, varscan2
- SCN7A | c.4073G>A p.R1358H | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs766963704, COSV69269732; called by muse, mutect2, varscan2
- TCF3 | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV99513510; called by muse, mutect2, varscan2
- TMEM45B | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99859192; called by muse, mutect2, varscan2
- USH2A | c.9437T>C p.L3146P | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100228420; called by muse, mutect2, varscan2
- VILL | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs377050534; called by muse, mutect2, varscan2
- DUOX1 | c.4321_4323del p.E1441del | In Frame Del (DEL) | VAF 10/110 reads (9%) | called by pindel, varscan2
- FUBP1 | c.1328_1329del p.I443Rfs*47 | Frame Shift Del (DEL) | VAF 40/67 reads (60%) | called by mutect2, pindel, varscan2
- HDAC11 | c.291del p.V98Lfs*14 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- MAP3K12 | c.2245_2248del p.S749Pfs*159 | Frame Shift Del (DEL) | VAF 15/150 reads (10%) | called by mutect2, pindel, varscan2
- MRC1 | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.014); called by muse, mutect2
- RBBP6 | c.5166_5167del p.Q1724Gfs*18 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel
- VPS35L | c.12_16del p.F4Lfs*6 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- ZNF292 | c.1572_1573del p.R527Gfs*8 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- C2CD3 | c.3021G>A p.E1007= | Silent (SNP) | VAF 11/142 reads (8%) | catalogued as COSV100486205; called by muse, mutect2
- DOCK2 | c.735C>T p.Y245= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs374307327; called by muse, mutect2, varscan2
- GSE1 | c.3471G>A p.R1157= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs1434334080, COSV99495994; called by muse, mutect2, varscan2
- OR9G1 | c.246G>C p.V82= | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as COSV100380217, COSV56450371, COSV56453955; called by muse, mutect2
- SERPINI2 | c.84A>G p.E28= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as COSV99247509; called by muse, mutect2, varscan2
